Somatic mutation profile of tumor specimen 0DPMS1 from CCDI case PBCEAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.2 years (4,095 days).
Specimen 0DPMS1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 030ba275-9d3a-4ee9-a142-d60818da1cd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dea94d29-5d14-4934-910b-d08565df7914

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Ins 2, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.18610G>A p.G6204S | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745735875; ClinVar: uncertain significance; called by muse, varscan2
- ANO1 | c.2423C>T p.T808M | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250438961; called by muse, mutect2, varscan2
- ATOH8 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 153/470 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs755604165; called by muse, mutect2, varscan2
- CCDC96 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 114/198 reads (58%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs746113925; called by muse, mutect2, varscan2
- CCN4 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as rs983447505; called by muse, mutect2, varscan2
- CILK1 | c.1433C>T p.T478M (on ENST00000350082 / NM_001375397.1; = p.T471M on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/536 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs56164633; ClinVar: uncertain significance; called by muse, mutect2
- DDX3X | c.1619C>A p.A540E (on ENST00000399959; = p.A541E on NM_001356.5) | Missense Mutation (SNP) | VAF 104/113 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863520, COSV67864045; called by muse, mutect2, varscan2
- HECTD4 | c.5123G>T p.R1708L | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs777490634, COSV101107220, COSV66397062; called by muse, mutect2, varscan2
- IL27 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 169/343 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs566281238; called by muse, mutect2, varscan2
- OR5B3 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 175/452 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs372384649; called by muse, mutect2, varscan2
- PCDHB10 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.341); catalogued as rs1229546777, COSV53378660, COSV99504735; called by muse, mutect2
- PTCH1 | c.654+1G>C p.X218_splice | Splice Site (SNP) | VAF 50/86 reads (58%) | catalogued as COSV59462098; called by muse, mutect2, varscan2
- PYHIN1 | c.423dup p.P142Tfs*3 | Frame Shift Ins (INS) | VAF 61/143 reads (43%) | catalogued as rs758393003; called by mutect2, varscan2
- ARHGAP18 | c.1873T>C p.F625L | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.1124del p.G375Efs*14 | Frame Shift Del (DEL) | VAF 173/454 reads (38%) | called by mutect2, pindel, varscan2
- GAA | c.2845dup p.V949Gfs*69 | Frame Shift Ins (INS) | VAF 64/668 reads (10%) | called by mutect2, pindel
- ITGA2 | c.3169A>G p.N1057D | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- MTHFD1 | c.676T>C p.W226R | Missense Mutation (SNP) | VAF 21/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PCDH7 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SORCS3 | c.2159T>C p.I720T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TRIP6 | c.1102T>G p.C368G | Missense Mutation (SNP) | VAF 139/344 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- WIF1 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK10 | c.879G>A p.S293= (on ENST00000353379 / NM_052988.5; = p.S222= on NM_052987.4) | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as rs1433692754; called by muse, mutect2
- HIPK2 | c.1083C>T p.Y361= | Silent (SNP) | VAF 124/267 reads (46%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.495C>T p.N165= | Silent (SNP) | VAF 40/308 reads (13%) | catalogued as rs1247701313, COSV53897799; called by muse, mutect2, varscan2
- SH2B3 | c.483C>T p.A161= | Silent (SNP) | VAF 45/291 reads (15%) | called by muse, mutect2, varscan2
- CLYBL | c.541-83G>A | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as rs1043686422, COSV59219414; called by muse, mutect2, varscan2
- E4F1 | c.1375+23G>A | Intron (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
